Surgical pathology report (de-identified scan), TCGA case TCGA-HV-A5A4, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HV-A5A4-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Pancreatic Ca.

Specimen : pancreas

GROSS:

Specimen status: Fresh

Operation: Distal pancreatectomy with splenectomy

Organs: Pancreas (12.0 x 3.5 x 3.0 cm)

Spleen (10.5 x 7.0 x 4.5 cm)

Regional lymph nodes dissection (No.3 and No.6)

Lesion: A pancreatic mass (body and tail)

Size: 7.9 x 2.4 x 1.4 cm

Feature: Dilated main pancreatic duct surrounded by
an ill-defined, pale tan to beige and firm mass
with multifocal cystic change containing mucinous fluid

Resection margin: Free of tumor

(0.3 cm from radial resection margin, 2.1 cm from proximal pancreatic margin)

Remainin parenchyma: Unremarkable

Spleen: Unremarkable

Representative sections submitted

ICD-0-3

Gross photo: Present

adenocarcinoma, duct, NOS 8500/3

Pott Site: pancreas, NOS C25.9

Blocks

CQCF : pancreas, body + tail
C25.1 C25.2

T1-6, pancreatic mass x 6

MS1-2, splenic hilum x 2

RM, pancreatic resection margin x 1

LN1, 'No.3' lymph nodes x 1

LN2, 'No.6' lymph nodes x 1

LN3-4, peripancreatic lymph nodes x 2

SP, spleen x 1

hw
12/10/12

MICROSCOPIC:

Tumor type: Ductal adenocarcinoma

[page 2 of 2]
Differentiation: Moderately differentiated
Tumor location: Pancreas (body and tail)
Depth of invasion: Tumor invades peripancreatic fat tissue
Lymphovascular invasion: Present
Perineural invasion: Present
Tumor size: 7.9 x 2.4 x 1.4 cm
Surgical margins: All surgical margins are free from tumor
Regional lymph nodes: Metastatic carcinoma (1/18)

DIAGNOSIS:

Pancreas, body and tail, distal pancreatectomy:
Ductal adenocarcinoma, moderately differentiated, infiltrating

Lymph node, regional, distal pancreatectomy:
Peripancreatic: Metastatic carcinoma, primary in pancreas (1/11)
Splenic hilum: No tumor present (0/4)

Lymph node, regional, dissection:
'No.3': No tumor present (0/1)
'No.6': No tumor present (0/2)

Spleen, splenectomy:
No pathologic abnormality

Diagnosis Inconsistency		X

Source: NCI Genomic Data Commons file 231e6e5b-54a9-4a2c-b772-56e8389b7e41 (TCGA-HV-A5A4.CC6BA3FE-519A-42AF-A414-46B18D654E68.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).